Somatic mutation profile of tumor specimen C3N-01716-03 (aliquot CPT0125130006) from CPTAC case C3N-01716, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 50.2 years (18,343 days).
Specimen C3N-01716-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8f5b37ba-3fd0-4637-bec6-0f44bed2cb26.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01716-31 (Blood Derived Normal), aliquot CPT0125150002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c75d4162-e065-49bb-b261-4e508653e8c6

The open-access MAF lists 41 somatic variants for this specimen: 26 protein-altering or splice-affecting, 11 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 11, Nonsense Mutation 3, Intron 2, Frame Shift Del 1, RNA 1, Frame Shift Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 47/311 reads (15%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 106/508 reads (21%) | hotspot (GDC flag); catalogued as rs397516435, CM941329, COSV52663748, COSV53125285, COSV53128268; ClinVar: pathogenic; called by muse, mutect2, varscan2
- C10orf90 | c.437G>A p.R146H | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372468399; called by muse, mutect2, varscan2
- FAM47A | c.989C>T p.P330L | Missense Mutation (SNP) | VAF 39/130 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60500739; called by muse, mutect2, varscan2
- GPR155 | c.290A>G p.N97S | Missense Mutation (SNP) | VAF 41/263 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.053); catalogued as rs376481034; called by muse, mutect2, varscan2
- HRH3 | c.1006C>T p.R336C | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as COSV100420461; called by muse, mutect2, varscan2
- LAMA1 | c.3665C>T p.P1222L | Missense Mutation (SNP) | VAF 161/440 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs762725918; called by muse, mutect2, varscan2
- LZTR1 | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 82/489 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as rs1469836617; called by muse, mutect2, varscan2
- METTL4 | c.313C>G p.H105D | Missense Mutation (SNP) | VAF 26/184 reads (14%) | SIFT tolerated (0.43); PolyPhen benign (0.01); catalogued as rs993396428, COSV55246724; called by muse, varscan2
- METTL4 | c.167C>G p.S56C | Missense Mutation (SNP) | VAF 33/251 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1426712682, COSV55249767; called by muse, varscan2
- OPRK1 | c.1081C>T p.R361* | Nonsense Mutation (SNP) | VAF 35/205 reads (17%) | catalogued as rs745533525, COSV55569565; called by muse, mutect2, varscan2
- OR10K2 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 85/445 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.259); catalogued as rs762306649, COSV59220549; called by muse, mutect2, varscan2
- PCDHA7 | c.1844C>T p.A615V | Missense Mutation (SNP) | VAF 78/431 reads (18%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.005); catalogued as COSV65346513; called by muse, mutect2, varscan2
- PRB1 | c.535C>T p.Q179* | Nonsense Mutation (SNP) | VAF 16/109 reads (15%) | catalogued as rs1408687259; called by muse, varscan2
- RAPGEF3 | c.961C>T p.R321W (on ENST00000389212; = p.R279W on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 58/332 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761190001; called by muse, mutect2, varscan2
- RNF113B | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 76/400 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as rs376379120; called by muse, mutect2, varscan2
- SV2B | c.583G>A p.V195M | Missense Mutation (SNP) | VAF 38/211 reads (18%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.993); catalogued as rs776050433, COSV100370469, COSV57700676, COSV57701598; called by muse, mutect2, varscan2
- ADCY2 | c.309del p.K104Sfs*9 | Frame Shift Del (DEL) | VAF 33/265 reads (12%) | called by mutect2, pindel, varscan2
- AMPH | c.321A>C p.E107D | Missense Mutation (SNP) | VAF 11/282 reads (4%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); called by muse, mutect2
- COPS7A | c.43T>G p.F15V | Missense Mutation (SNP) | VAF 14/472 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- GLB1L2 | c.1507G>A p.G503S | Missense Mutation (SNP) | VAF 39/215 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KDM6A | c.3160dup p.R1054Kfs*5 | Frame Shift Ins (INS) | VAF 31/111 reads (28%) | called by mutect2, pindel, varscan2
- METTL4 | c.57C>G p.I19M | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); called by muse, varscan2
- RALGAPB | c.4241A>C p.N1414T | Missense Mutation (SNP) | VAF 27/179 reads (15%) | SIFT tolerated (0.49); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SYMPK | c.499G>A p.D167N | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TNR | c.3502T>G p.C1168G | Missense Mutation (SNP) | VAF 53/264 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AGPAT3 | c.396C>T p.I132= | Silent (SNP) | VAF 47/256 reads (18%) | catalogued as rs777102711; called by muse, mutect2, varscan2
- APBA1 | c.81C>T p.A27= | Silent (SNP) | VAF 27/89 reads (30%) | catalogued as rs902513997, COSV55237360; called by muse, mutect2, varscan2
- DPP10 | c.345A>G p.L115= | Silent (SNP) | VAF 18/104 reads (17%) | catalogued as rs1382108558; called by muse, mutect2, varscan2
- GREB1 | c.5760C>T p.D1920= | Silent (SNP) | VAF 41/242 reads (17%) | catalogued as rs780513457, COSV52180533, COSV52191810; called by muse, mutect2, varscan2
- NOTCH1 | c.3141C>T p.C1047= | Silent (SNP) | VAF 49/135 reads (36%) | catalogued as rs1221606038; called by muse, mutect2, varscan2
- OTOG | c.825A>G p.P275= | Silent (SNP) | VAF 80/367 reads (22%) | called by muse, mutect2, varscan2
- SATB1 | c.180G>A p.S60= | Silent (SNP) | VAF 64/334 reads (19%) | catalogued as rs138373358; called by muse, mutect2, varscan2
- SHISAL2B | c.285G>A p.T95= | Silent (SNP) | VAF 32/153 reads (21%) | catalogued as rs563854983, COSV66619529; called by muse, mutect2, varscan2
- SPATA31A7 | c.264G>A p.P88= | Silent (SNP) | VAF 115/680 reads (17%) | catalogued as rs201157502; called by muse, mutect2, varscan2
- WTIP | c.462C>G p.G154= | Silent (SNP) | VAF 24/93 reads (26%) | called by muse, mutect2, varscan2
- ZHX2 | c.1161C>T p.T387= | Silent (SNP) | VAF 73/379 reads (19%) | catalogued as rs530836451; called by muse, mutect2, varscan2
- HARS2 | c.109-21T>A | Intron (SNP) | VAF 77/457 reads (17%) | called by muse, mutect2, varscan2
- IGHEP1 | n.530G>A | RNA (SNP) | VAF 81/446 reads (18%) | catalogued as rs773026581; called by muse, mutect2, varscan2
- PNMA6A | chrX:153076256 T>A | 3'Flank (SNP) | VAF 4/31 reads (13%) | called by mutect2, varscan2
- ZNF655 | c.136+3194C>T | Intron (SNP) | VAF 59/298 reads (20%) | catalogued as rs776026660; called by muse, mutect2, varscan2
